Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9I3, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9I3-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Final Diagnosis

- A. SPLEEN, SPLENECTOMY:
Spleen with no significant pathologic changes.
There is no evidence of malignancy.
- B. STOMACH, POSTERIOR GASTRIC WALL TUMOR, RESECTION:
Consistent with leiomyosarcoma.
Tumor size 9 x 4 cm.
The surgical margins are involved by tumor.
- C. STOMACH, POLYP NO. 1, BIOPSY:
Gastric mucosa with foveolar cell hyperplasia and parietal cell hyperplasia.
There is no evidence of malignancy.
- D. STOMACH, POLYP NO. 2, BIOPSY:
Gastric mucosa with foveolar and parietal cell hyperplasia.
There is no evidence of malignancy.
- E. STOMACH, ADDITIONAL POSTERIOR GASTRIC WALL, RESECTION:
Gastric mucosa with foveolar and parietal cell hyperplasia.
There is no evidence of malignancy.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Comment

Part B: This is tumor composed of intersecting spindle cells with cellular pleomorphism, a mitotic rate of 67 mitoses/25 high-power fields, and no evidence of tumor necrosis. The tumor is positive for actin, desmin, and focally and weakly positive for CD34. The tumor is negative for CD117 and keratin. These results support the above diagnosis. The stains were performed on block B1 with appropriate controls.

Specimen(s) Received

- A SPLEEN
B POSTERIOR GASTRIC WALL TUMOR
C GASTRIC POLYP #1 FS
D GASTRIC POLYP #2 FS
E ADDITIONAL POSTERIOR GASTRIC WALL FS

Clinical History

GASTRIC LEIOMYOSARCOMA.

ICD-O-3
Leiomyosarcoma NOS 8890/3
GUP
Retroperitoneum C48.0
Stomach, posterior wall C16.8
QJ 4/23/14

[page 2 of 3]
Intraoperative Consultation

A. SPLEEN:

No gross lesions identified. Will hold small piece of spleen, if needed, in flow labs.

Per Dr.

FSC1: FUNDIC GLAND POLYP:

Benign gastric tissue.

FSE1: ADDITIONAL POSTERIOR GASTRIC WALL:

Benign gastric tissue.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr.

I, _____ MD, have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. Received fresh, labeled "spleen" and consists of an intact dark red-tan splenectomy specimen, 208.9 g, 16.4 x 7.8 x 4.5 cm. The capsule is intact, pitted and dull. Sectioned, the cut surfaces exhibit deep red, smooth, glistening parenchyma with moderate white pulp. No lesion or cysts are noted. Focal hemorrhage is identified (5%). Representative sections are submitted in A1-A4 as labeled:

A1: Spleen, full thickness with capsule
A2-A4: Random sleep

The specimen is not submitted for Tissue Procurement Laboratory.

B. Received fresh, labeled "posterior gastric wall tumor" and consists of an unoriented, grossly distorted, indurated, gastric mass, 740.7 g, 18.5 x 9.0 x 8.5 cm. The mass is roughly ovoid, with an ulcerated cavity with thickened (3-4 cm) heaped up border, 9 x 4 cm. The mucosa is tan-gray and extensively nodular with granularity and there are smooth, glistening foci absent of normal mucosa. The serosa is intact, smooth and inked black with attached soft tissue, 21 x 10.5 x 1.5 cm. The serosa is inked black. Sectioned, the mass cut surfaces reveal white-pale gray, smooth, whorled, lobulated, viable tissue involving the entire mass. The tumor invades the mucosa, extending 4.5 cm depth and replaces submucosa and muscularis propria; but, does not invade the serosa. There is minimal necrosis seen. No hemorrhage, cyst or calcifications are noted. Lymph nodes of the soft tissue are not isolated. Representative sections are submitted in B1-B17 as labeled:

B1-B5: Mass with serosa
B6-B10: Mass with mucosa
B11-B15: Random central mass
B16: Representative of lateral margin
B17: Representative of opposite lateral margin

[page 3 of 3]
The specimen is submitted for

, as reflected in cassette B15.

C. Received fresh for frozen section consult, labeled "gastric polyp No. 1" and consists of a 4 mm pink, soft nodule. The specimen is submitted entirely intact in FSC1.

The specimen is not submitted for

D. Received fresh for frozen section consult, labeled "gastric polyp No. 2" and consists of a pale tan-gray, ovoid, rubbery nodule, 8 x 7 x 5 mm. The nodule is submitted entirely intact in FSD1.

The specimen is not submitted for

E. Received fresh for frozen section consult, labeled "additional posterior gastric wall: stitch -true margin" and consists of an oriented, elongated, rubbery, gastric excision, 9.3 x 3.1 x 1.4 cm. The mucosa is pale gray with multiple foci of hemorrhage. There is a chalky white, firm, defined lesion, 2.7 x 1.4 cm, 2 cm from resection margin. The serosa is ragged with scant soft tissue. The cut surfaces show confinement of the lesion to the mucosa, with no involvement of other structures. No necrosis, hemorrhage or cyst is noted. Representative sections are submitted in FSE1-E9 as labeled:

FSE1-FSE3:	Frozen section of true margin, tangential
E4-E8:	Gastric lesion, entirely
E9:	Normal gastric mucosa

The specimen is not submitted to

Criteria	hw 1/2/14	Yes	No

Source: NCI Genomic Data Commons file 42e4062c-6b76-4963-83d7-87a58f893e97 (TCGA-3B-A9I3.4AF84B04-91C2-4B22-AEEF-F1BF73A1B9F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).